CCDI case PBBNVH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/3b1e8d7a-cb4d-4e0c-a91f-fb97f4c36082

Demographics
Sex at birth: female; Race: asian.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.3 years (1,584 days).

Biospecimens (3 samples)
- Sample 0DDIK9: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DDIKH: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DDIKM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
